Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB30, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB30-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-O 5

Fibromyxosarcoma 8811/3
Site - thigh NOS 049.2
JW3/10/14

Clinical Diagnosis & History:

with enlarging left medial thigh mass.

Specimens Submitted:

1: SP: Sarcoma, anterior left thigh

DIAGNOSIS:

- 1) SOFT TISSUE, LEFT ANTERIOR THIGH; EXCISION:
- HIGH GRADE MYXOFIBROSARCOMA (10 x 5.1 x 4.5 CM), INVOLVING SKELETAL MUSCLE.
- FOCAL AREAS OF NECROSIS ARE PRESENT.
- SURGICAL MARGINS ARE FREE, BUT THE TUMOR COMES CLOSE (WITHIN 1 MM) TO THE PROXIMAL ASPECT OF THE DEEP MARGIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh, labeled "Sarcoma, anterior left thigh. One stitch proximal and lateral, two stitches distal and medial". It consists of one ovoid portion of skeletal muscle that contains a firm tumor. The specimen has attached a flat piece of lobulated, fatty tissue that is grossly unremarkable. The overall measurements of the specimen are 17 x 15 x 6.5 cm. One surgical stitch designates the proximal end of the specimen and two surgical stitches designate the distal aspect. On external examination, all soft tissue margins are negative for tumor. No skin ellipse is identified. The specimen is serially sectioned to demonstrate an ovoid tumor that measures 10 x 5.1 x 4.5 cm. The mass is well-circumscribed but lacks encapsulation. The bulk of the tumor is localized within skeletal muscle but the tumor focally abuts the available portion of yellow lobulated

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
fatty tissue. Gross examination demonstrates close extension of the tumor to the proximal aspect of the deep margin, but there is no definitive extension of the tumor to the ink. All surgical margins are inked black. Representative sections are submitted.

Summary of Sections:

PDM - Proximal aspect of deep margin
MDM - Mid aspect of deep margin
DDM - Distal aspect of the deep margin
RT - Representative tumor

Summary of Sections:

Part 1: SP: Sarcoma, anterior left thigh

Block	Sect.	Site	PCs
1		ddm	1
2		mdm	2
1		pdm	2
7		rt	7

** End of Report **

Criteria	lw 1/22/14	Yes	No
Prior Malignancy History	Breast DCIS	✓	✓

Source: NCI Genomic Data Commons file 558b95da-2bf1-4843-8a15-d4869a3b17ac (TCGA-DX-AB30.7E4E3C1F-9768-46EF-835E-52F663E3ED2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).